Somatic mutation profile of tumor specimen TCGA-09-2056-01B (aliquot TCGA-09-2056-01B-01W-0722-08) from TCGA case TCGA-09-2056, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.6 years (22,864 days).
Specimen TCGA-09-2056-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6c82434-08e2-4bff-801e-42bb8aeb55dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2056-11A (Solid Tissue Normal), aliquot TCGA-09-2056-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed604620-eb1b-4872-9f8c-a44ea85e6c6b

The open-access MAF lists 96 somatic variants for this specimen: 81 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 1, Intron 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PALB2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 94/241 reads (39%) | catalogued as rs587776411, CM143124, COSV55168698; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2109C>G p.I703M | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV57057689; called by muse, mutect2, varscan2
- ACCS | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.178); catalogued as COSV55459633; called by muse, mutect2, varscan2
- BTNL9 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV59798166; called by muse, mutect2, varscan2
- CARD14 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100712601; called by muse, mutect2, varscan2
- CASC3 | c.968G>C p.R323P | Missense Mutation (SNP) | VAF 356/1230 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52866345, COSV52868738; called by muse, mutect2, varscan2
- CASP8AP2 | c.2708C>G p.S903C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52748918; called by muse, mutect2, varscan2
- CCDC116 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV53038449; called by muse, varscan2
- CD5L | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100941265, COSV63822789; called by muse, mutect2, varscan2
- CDH9 | c.1226A>T p.D409V | Missense Mutation (SNP) | VAF 93/301 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50372637; called by muse, mutect2, varscan2
- CHST2 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58886599; called by muse, varscan2
- CSPP1 | c.2620G>C p.D874H (on ENST00000676605; = p.D833H on NM_024790.6) | Missense Mutation (SNP) | VAF 92/124 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51589916; called by muse, mutect2, varscan2
- DMXL2 | c.1703T>G p.I568R | Missense Mutation (SNP) | VAF 142/176 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV51852319; called by muse, mutect2, varscan2
- DNAJB4 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100883474; called by muse, mutect2
- DSCAML1 | c.1829G>T p.R610L (on ENST00000321322; = p.R550L on NM_020693.4) | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58386107, COSV58398791; called by muse, mutect2, varscan2
- EDIL3 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 166/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99678365; called by muse, mutect2, varscan2
- EP400 | c.5813A>C p.H1938P | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs75778935; called by muse, mutect2, varscan2
- ERCC6L | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 74/1049 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs777094514, COSV100559215; called by muse, mutect2
- FADS2 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV53901064; called by muse, varscan2
- FAM71A | c.317A>T p.K106M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54235298, COSV54236674; called by muse, mutect2, varscan2
- FBN2 | c.5243C>T p.T1748I | Missense Mutation (SNP) | VAF 83/108 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs746036536, COSV52534416; called by muse, mutect2, varscan2
- FBXO11 | c.1141A>C p.S381R (on ENST00000403359 / NM_001190274.2; = p.S297R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs747726413, COSV100319805; called by muse, mutect2, varscan2
- FYB2 | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58587697; called by muse, mutect2, varscan2
- GAB2 | c.1509C>G p.S503R (on ENST00000361507 / NM_080491.3; = p.S465R on NM_012296.3) | Missense Mutation (SNP) | VAF 160/384 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1308890517, COSV60870072; called by muse, mutect2, varscan2
- GOLGB1 | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 147/392 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.243); catalogued as COSV100511333; called by muse, mutect2, varscan2
- HAO1 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV101113279; called by muse, mutect2
- HPSE2 | c.479A>T p.K160I | Missense Mutation (SNP) | VAF 163/414 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs763664579, COSV65197257; called by muse, mutect2, varscan2
- ISYNA1 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV54209555, COSV54211763; called by muse, mutect2, varscan2
- KDM5C | c.4286C>T p.P1429L | Missense Mutation (SNP) | VAF 171/410 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556832824, COSV64767609; called by muse, mutect2, varscan2
- LRP1B | c.5245T>C p.W1749R | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67256628; called by muse, mutect2, varscan2
- LRRIQ1 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs752166047, COSV67835784; called by muse, mutect2
- LRRN4 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV101125503; called by muse, varscan2
- LRRN4 | c.630T>G p.D210E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101125504; called by muse, mutect2, varscan2
- LZTR1 | c.652-2A>C p.X218_splice | Splice Site (SNP) | VAF 55/66 reads (83%) | catalogued as rs746294125, COSV53150119; called by muse, mutect2, varscan2
- MAGEB6B | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 83/116 reads (72%) | SIFT tolerated (0.4); PolyPhen benign (0.34); catalogued as rs779672546; called by muse, mutect2, varscan2
- MEAK7 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV59144417, COSV59145063; called by muse, mutect2, varscan2
- MED13 | c.3259G>C p.D1087H | Missense Mutation (SNP) | VAF 95/173 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67265927; called by muse, mutect2, varscan2
- MEF2A | c.1129T>A p.S377T (on ENST00000557942 / NM_001319206.2; = p.S371T on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as rs1037830845, COSV57536211; called by muse, mutect2, varscan2
- MID1 | c.1180G>C p.A394P | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as rs948448691, COSV58197748; called by muse, mutect2, varscan2
- MS4A1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 219/527 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as rs370620216, COSV61942675; called by muse, mutect2, varscan2
- MT4 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 235/637 reads (37%) | catalogued as COSV54642265, COSV54642871; called by muse, mutect2, varscan2
- MYLK | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1376046700, COSV60617874; called by muse, mutect2, varscan2
- NAF1 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56805451; called by muse, mutect2, varscan2
- NAV3 | c.3504C>G p.S1168R | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV57101713; called by muse, mutect2, varscan2
- NLRC4 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 198/549 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as rs769708690, COSV61594113; called by muse, mutect2, varscan2
- NLRX1 | c.2266G>C p.G756R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.463); catalogued as COSV52706322, COSV99424669; called by muse, mutect2, varscan2
- NT5C1A | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV52495807; called by muse, mutect2, varscan2
- NUP205 | c.1043C>G p.A348G | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.145); catalogued as rs1281409294, COSV53663998; called by muse, mutect2, varscan2
- OPN4 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54118260; called by muse, mutect2, varscan2
- OR10T2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57782742; called by muse, mutect2, varscan2
- OR1D2 | c.526T>A p.Y176N | Missense Mutation (SNP) | VAF 145/181 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV58922167; called by muse, mutect2, varscan2
- OR51F2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV59065602; called by muse, mutect2, varscan2
- OSGEP | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 561/707 reads (79%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as rs1047263969, COSV99248126; called by muse, mutect2, varscan2
- PCDHB2 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as COSV52035855; called by muse, mutect2, varscan2
- PGK2 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 157/189 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59164901, COSV59165073; called by muse, varscan2
- PI4KB | c.1582C>G p.P528A (on ENST00000368873 / NM_001369623.1; = p.P540A on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/818 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55017746, COSV55020283; called by muse, mutect2, varscan2
- PKHD1L1 | c.10205T>G p.L3402* | Nonsense Mutation (SNP) | VAF 8/9 reads (89%) | catalogued as rs1430056916, COSV65749407; called by muse, mutect2, varscan2
- PLB1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV59832507; called by muse, mutect2, varscan2
- PRR30 | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV53207506; called by muse, mutect2, varscan2
- PSPH | c.678A>T p.*226Yext*39 | Nonstop Mutation (SNP) | VAF 70/147 reads (48%) | catalogued as COSV51912378; called by muse, mutect2, varscan2
- RNF19A | c.926T>A p.I309K | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61994333; called by muse, mutect2, varscan2
- RTKN | c.1111C>G p.L371V (on ENST00000272430 / NM_001015055.2; = p.L358V on NM_033046.2) | Missense Mutation (SNP) | VAF 306/642 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV99269824; called by muse, mutect2, varscan2
- SCRT2 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55730298; called by muse, mutect2, varscan2
- SGCD | c.15G>T p.Q5H (on ENST00000435422 / NM_001128209.2; = p.Q6H on NM_000337.5) | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100550735; called by muse, mutect2, varscan2
- SLITRK3 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs745603572, COSV53848285; called by muse, mutect2, varscan2
- SULF1 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 228/293 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV52689160; called by muse, mutect2, varscan2
- SYNE2 | c.14783T>G p.L4928R | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59962916; called by muse, varscan2
- SYNE4 | c.319A>G p.N107D | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53325441; called by muse, mutect2, varscan2
- TPCN2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99593818; called by muse, mutect2, varscan2
- TRAPPC8 | c.4073+1G>A p.X1358_splice | Splice Site (SNP) | VAF 47/129 reads (36%) | catalogued as COSV51975417; called by muse, mutect2, varscan2
- TRIOBP | c.3458C>G p.S1153C | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV60382164; called by muse, mutect2, varscan2
- TTN | c.2443C>G p.H815D (on ENST00000591111; = p.H769D on NM_003319.4) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | PolyPhen probably damaging (0.996); catalogued as COSV60243273; called by muse, mutect2, varscan2
- UPF2 | c.1760C>G p.A587G | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62662642; called by muse, mutect2, varscan2
- VPS35L | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); catalogued as COSV51988417; called by muse, mutect2, varscan2
- WAPL | c.3517G>C p.G1173R | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV53938607; called by muse, mutect2, varscan2
- ZC4H2 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 265/689 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as COSV100565103; called by muse, mutect2, varscan2
- ADAMTS9 | c.4746_4749del p.C1582Wfs*15 | Frame Shift Del (DEL) | VAF 233/719 reads (32%) | called by mutect2, pindel, varscan2
- COPB2 | c.2375_2376del p.T792Rfs*3 | Frame Shift Del (DEL) | VAF 258/801 reads (32%) | called by mutect2, pindel, varscan2
- GSTT2B | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- OVGP1 | c.809dup p.K271Qfs*4 | Frame Shift Ins (INS) | VAF 198/592 reads (33%) | called by mutect2, pindel, varscan2
- ZFPM2 | c.3401_3408del p.F1134Sfs*18 | Frame Shift Del (DEL) | VAF 15/22 reads (68%) | called by mutect2, pindel, varscan2
- ARAF | c.1683C>T p.P561= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as COSV51694550; called by muse, mutect2, varscan2
- GAL3ST4 | c.486G>A p.A162= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs776484864, COSV57587695; called by muse, mutect2, varscan2
- GIMAP4 | c.117C>T p.T39= | Silent (SNP) | VAF 98/189 reads (52%) | catalogued as rs367979869; called by muse, mutect2, varscan2
- HOXA1 | c.555C>A p.A185= | Silent (SNP) | VAF 92/222 reads (41%) | catalogued as COSV56067370; called by muse, mutect2, varscan2
- KDM5A | c.999A>G p.G333= | Silent (SNP) | VAF 176/584 reads (30%) | catalogued as COSV101239007; called by muse, mutect2, varscan2
- KIT | c.978C>T p.N326= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs148594615; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- NLRP1 | c.1308G>A p.A436= | Silent (SNP) | VAF 34/41 reads (83%) | catalogued as rs200867395, COSV52574053; called by muse, mutect2, varscan2
- NTHL1 | c.846G>A p.L282= (on ENST00000219066; = p.L274= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV54593858; called by muse, mutect2, varscan2
- PAOX | c.1203G>T p.L401= | Silent (SNP) | VAF 123/282 reads (44%) | catalogued as COSV99530004; called by muse, varscan2
- SCARA5 | c.882C>T p.H294= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as rs751855526, COSV100108018; called by muse, mutect2, varscan2
- TRIM58 | c.1374G>A p.L458= | Silent (SNP) | VAF 382/1160 reads (33%) | catalogued as rs751500557, COSV63571653, COSV63571955; called by muse, mutect2, varscan2
- USH2A | c.12906G>A p.R4302= | Silent (SNP) | VAF 235/849 reads (28%) | catalogued as COSV56412094; called by muse, mutect2, varscan2
- VCAN | c.6795T>C p.T2265= | Silent (SNP) | VAF 79/136 reads (58%) | catalogued as COSV54112912; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421103del | Intron (DEL) | VAF 60/243 reads (25%) | catalogued as COSV66165697; called by pindel, varscan2*
- UPF2 | c.*259G>C | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100707389; called by muse, mutect2, varscan2
